Somatic mutation profile of tumor specimen TCGA-CV-A6JZ-01A (aliquot TCGA-CV-A6JZ-01A-11D-A31L-08) from TCGA case TCGA-CV-A6JZ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 68.9 years (25,182 days).
Specimen TCGA-CV-A6JZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1aea0a8-2f74-4d21-a8e3-1cc0fdedc72e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A6JZ-10A (Blood Derived Normal), aliquot TCGA-CV-A6JZ-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad3fe979-1c1d-49c4-a21c-2ebc9578203c

The open-access MAF lists 111 somatic variants for this specimen: 80 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 28, Nonsense Mutation 5, Frame Shift Del 4, Splice Site 3, Frame Shift Ins 2, RNA 2, Translation Start Site 1, In Frame Del 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 26/86 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCD4 | c.39G>A p.R13= | Splice Region (SNP) | VAF 13/84 reads (15%) | catalogued as COSV100083953; called by muse, mutect2, varscan2
- ACTL6A | c.953C>A p.S318* | Nonsense Mutation (SNP) | VAF 24/199 reads (12%) | catalogued as COSV101199590; called by muse, mutect2, varscan2
- AMBP | c.776T>C p.F259S | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748106245, COSV99468688; called by muse, mutect2, varscan2
- ANKFN1 | c.911G>T p.R304M | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100592983; called by muse, mutect2, varscan2
- ANO9 | c.1787-2A>T p.X596_splice | Splice Site (SNP) | VAF 14/57 reads (25%) | catalogued as COSV100229727; called by muse, mutect2, varscan2
- ARHGAP22 | c.2054G>A p.G685E | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1341707809, COSV99984210; called by muse, mutect2, varscan2
- ARHGEF6 | c.686T>C p.V229A | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs755916219, COSV51696232, COSV99166323; called by muse, varscan2
- ARMCX5-GPRASP2 | c.919A>G p.I307V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.206); catalogued as COSV100771752; called by muse, mutect2, varscan2
- ATP8A1 | c.525-2A>C p.X175_splice | Splice Site (SNP) | VAF 7/76 reads (9%) | catalogued as COSV100044614; called by muse, mutect2, varscan2
- BAZ2A | c.5257T>G p.F1753V | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.727); catalogued as COSV99464423; called by muse, mutect2, varscan2
- BCL9 | c.319T>C p.S107P | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99324286; called by muse, mutect2, varscan2
- BICC1 | c.538A>C p.S180R | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs757602153, COSV100874645; called by muse, mutect2, varscan2
- BMS1 | c.2119_2121del p.D707del | In Frame Del (DEL) | VAF 10/76 reads (13%) | catalogued as rs1312645249; called by pindel, varscan2
- C1orf112 | c.1064C>A p.S355Y | Missense Mutation (SNP) | VAF 84/485 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99609263; called by muse, mutect2, varscan2
- CABLES2 | c.1042T>A p.F348I | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99652888; called by muse, mutect2, varscan2
- CASQ2 | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.86); catalogued as COSV99796902; called by muse, mutect2, varscan2
- CDH11 | c.1604T>A p.I535N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV99216855; called by muse, mutect2, varscan2
- CLK4 | c.1364T>A p.M455K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100308775; called by muse, mutect2, varscan2
- COL1A2 | c.3427A>C p.N1143H | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV99798167; called by muse, mutect2, varscan2
- DCBLD1 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.828); catalogued as rs767019993, COSV99756913; called by muse, mutect2, varscan2
- DLC1 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as COSV52317037; called by muse, mutect2, varscan2
- DSCAML1 | c.1565C>T p.S522L (on ENST00000321322; = p.S462L on NM_020693.4) | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.396); catalogued as rs935338538, COSV58387224; called by muse, mutect2, varscan2
- ECT2L | c.2553T>A p.H851Q | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99238309; called by muse, mutect2, varscan2
- FAT1 | c.5006C>G p.S1669* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV71676002; called by muse, mutect2, varscan2
- GLIS3 | c.1283A>T p.N428I | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100173090; called by muse, mutect2
- GOLGA4 | c.4529A>G p.E1510G | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV100728589; called by muse, mutect2, varscan2
- GPRASP1 | c.3809A>G p.Y1270C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1037381961, COSV100850890; called by muse, mutect2, varscan2
- GRM5 | c.547A>G p.T183A | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV100549734; called by muse, mutect2, varscan2
- HMGCS1 | c.43A>G p.K15E | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.037); catalogued as COSV100284875; called by muse, mutect2, varscan2
- HYI | c.586G>A p.A196T (on ENST00000372434 / NM_001330526.2; = p.A171T on NM_031207.6) | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.139); catalogued as COSV100981160; called by muse, mutect2
- KALRN | c.2167G>A p.D723N | Missense Mutation (SNP) | VAF 206/426 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99561646; called by muse, mutect2, varscan2
- KCNJ3 | c.970G>T p.G324C | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99715072; called by muse, mutect2, varscan2
- KCTD19 | c.390G>A p.W130* | Nonsense Mutation (SNP) | VAF 16/112 reads (14%) | catalogued as COSV100430596; called by muse, mutect2, varscan2
- KIF3B | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.853); catalogued as rs940799632, COSV65228902; called by muse, mutect2
- LGR6 | c.232C>A p.L78I (on ENST00000367278 / NM_001017403.1; = p.L26I on NM_021636.3) | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV99705829; called by muse, mutect2, varscan2
- LRP5 | c.562A>T p.I188F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV99591197; called by muse, mutect2, varscan2
- MGAM | c.2651T>A p.V884E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV101527341; called by muse, mutect2
- MS4A3 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs780015751, COSV53934738; called by muse, mutect2, varscan2
- MS4A6A | c.698C>A p.S233Y | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.276); catalogued as COSV100124484; called by muse, mutect2, varscan2
- MUC16 | c.24403G>T p.A8135S | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.266); catalogued as COSV101197487; called by muse, mutect2, varscan2
- MYH10 | c.245C>G p.P82R | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99343807; called by muse, mutect2, varscan2
- MYOM2 | c.1363T>C p.F455L | Missense Mutation (SNP) | VAF 52/257 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs1458419587, COSV100036396; called by muse, mutect2, varscan2
- NEB | c.12335A>G p.Y4112C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99413732; called by muse, mutect2, varscan2
- NOP14 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs149998901; called by muse, mutect2, varscan2
- NPFFR2 | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.041); catalogued as COSV100440200; called by muse, mutect2, varscan2
- NRXN3 | c.2938A>T p.I980F (on ENST00000335750 / NM_001330195.2; = p.I607F on NM_004796.6) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.215); catalogued as COSV100199733; called by muse, mutect2
- OIT3 | c.1582G>A p.G528S | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.041); catalogued as rs780018350, COSV100467526; called by muse, mutect2, varscan2
- OR10AG1 | c.205A>C p.I69L | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100399963; called by muse, mutect2, varscan2
- OR10AG1 | c.62T>C p.I21T | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs766067085, COSV100399964; called by muse, mutect2, varscan2
- OR2C3 | c.47T>A p.L16Q | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100825576; called by muse, mutect2, varscan2
- OR4P4 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100111499; called by muse, mutect2, varscan2
- OR4P4 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100111502, COSV58920801; called by muse, mutect2, varscan2
- OR51I2 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100413253, COSV100413433; called by muse, mutect2, varscan2
- OR5I1 | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1242407302, COSV100041163; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.656A>G p.E219G (on ENST00000259318 / NM_001136562.3; = p.E450G on NM_007203.5) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99394578; called by muse, mutect2, varscan2
- PATJ | c.3671-1G>T p.X1224_splice | Splice Site (SNP) | VAF 12/40 reads (30%) | catalogued as rs868364490, COSV100219328; called by muse, mutect2, varscan2
- PHF3 | c.2944A>T p.R982* | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | catalogued as COSV100012771; called by muse, mutect2, varscan2
- PKN2 | c.407A>T p.N136I | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV100281254; called by muse, mutect2, varscan2
- PRKG1 | c.461T>A p.L154Q | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as COSV100907613; called by muse, mutect2, varscan2
- SALL2 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as rs753189477, COSV58104956; called by muse, mutect2, varscan2
- SFSWAP | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV55520375, COSV55525270; called by muse, mutect2
- SWT1 | c.2218G>T p.V740F | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV100832977; called by muse, mutect2, varscan2
- TAS2R46 | c.887A>G p.H296R | Missense Mutation (SNP) | VAF 8/251 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1184862842, COSV101113898; called by muse, mutect2
- TCERG1 | c.2476C>T p.R826C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755170489, COSV57034377; called by muse, mutect2, varscan2
- TEX33 | c.737A>T p.D246V (on ENST00000381821 / NM_001163857.2; = p.D161V on NM_178552.4) | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101111469; called by muse, mutect2, varscan2
- TMEM132D | c.1148T>C p.I383T | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV101395894; called by muse, mutect2, varscan2
- TMPRSS13 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.28); PolyPhen probably damaging (1); catalogued as COSV101471347; called by muse, mutect2
- TNKS1BP1 | c.4840C>T p.R1614W | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs771893296, COSV100835734; called by muse, mutect2, varscan2
- TOMM5 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 60/125 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.658); catalogued as COSV100353524; called by muse, mutect2, varscan2
- ZNF433 | c.1810C>T p.R604* | Nonsense Mutation (SNP) | VAF 9/75 reads (12%) | catalogued as rs200904369; called by muse, mutect2, varscan2
- ZNF536 | c.2096G>T p.G699V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1177918706, COSV100834509; called by muse, mutect2, varscan2
- ZNF804B | c.2826T>A p.S942R | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.031); catalogued as COSV100301278; called by muse, mutect2, varscan2
- ZNRD2 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100326050; called by muse, mutect2, varscan2
- ABHD5 | c.792_796delinsTTCT p.I265Sfs*29 (on ENST00000458276 / NM_001365650.1; = p.H327Ffs*15 on NM_016006.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 25/119 reads (21%) | called by pindel, varscan2*
- KCNK3 | c.467_470del p.M156Tfs*91 | Frame Shift Del (DEL) | VAF 16/111 reads (14%) | called by mutect2, pindel, varscan2
- NELFA | c.1408dup p.I470Nfs*39 (on ENST00000542778; = p.I459Nfs*39 on NM_005663.5) | Frame Shift Ins (INS) | VAF 10/97 reads (10%) | called by mutect2, varscan2
- PRKD1 | c.271del p.E91Nfs*27 | Frame Shift Del (DEL) | VAF 9/73 reads (12%) | called by mutect2, pindel, varscan2
- PTCH2 | c.1105_1114del p.E369Pfs*40 | Frame Shift Del (DEL) | VAF 26/159 reads (16%) | called by mutect2, pindel, varscan2
- TRIM24 | c.2979dup p.E994* (on ENST00000343526 / NM_015905.3; = p.E960* on NM_003852.4) | Frame Shift Ins (INS) | VAF 6/45 reads (13%) | called by mutect2, pindel, varscan2
- ABL1 | c.1266C>A p.V422= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV59345112; called by muse, mutect2
- APOB | c.7938C>A p.S2646= | Silent (SNP) | VAF 29/203 reads (14%) | catalogued as COSV51927595, COSV99262988; called by muse, mutect2, varscan2
- CAV1 | c.141G>A p.K47= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV100591851; called by muse, mutect2, varscan2
- GPR39 | c.1305A>T p.S435= | Silent (SNP) | VAF 9/92 reads (10%) | catalogued as rs1172559482, COSV100256775; called by muse, mutect2, varscan2
- GRM8 | c.846C>T p.A282= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs142836470; ClinVar: likely benign; called by muse, varscan2
- GRM8 | c.783A>G p.E261= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV100279738, COSV58879036; called by muse, varscan2
- ITPKB | c.2649C>T p.F883= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99683533; called by muse, mutect2, varscan2
- JAM3 | c.552C>A p.S184= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV100137723; called by muse, mutect2, varscan2
- MAT1A | c.486C>T p.A162= | Silent (SNP) | VAF 34/151 reads (23%) | catalogued as rs1412871923, COSV64744833; called by muse, mutect2, varscan2
- NCLN | c.681C>T p.A227= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as COSV99859609; called by muse, mutect2, varscan2
- NPHP4 | c.4119G>A p.R1373= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100976673, COSV65397248; called by muse, mutect2, varscan2
- NR3C2 | c.201A>G p.K67= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as COSV100678573; called by muse, mutect2, varscan2
- OR10AG1 | c.399T>C p.I133= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV100399961; called by muse, varscan2
- OR2J2 | c.120G>A p.L40= | Silent (SNP) | VAF 31/185 reads (17%) | catalogued as COSV65847742; called by muse, mutect2, varscan2
- PCED1B | c.288C>T p.R96= | Silent (SNP) | VAF 30/207 reads (14%) | catalogued as rs1044302465, COSV101423587, COSV101423685; called by muse, mutect2, varscan2
- PRR14 | c.744G>A p.P248= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as rs764668239, COSV99788237; called by muse, mutect2, varscan2
- RP1 | c.2988C>T p.A996= | Silent (SNP) | VAF 51/200 reads (26%) | catalogued as COSV99605850; called by muse, mutect2, varscan2
- RPS6KA1 | c.1005G>A p.K335= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as rs540126898, COSV100837858; called by muse, mutect2, varscan2
- SENP6 | c.753A>G p.L251= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV100518897; called by muse, mutect2, varscan2
- SLC25A2 | c.237G>A p.S79= | Silent (SNP) | VAF 48/121 reads (40%) | catalogued as rs782533043, COSV99508129; called by muse, mutect2, varscan2
- TMPRSS2 | c.66G>A p.P22= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as rs769586352, COSV100151003; called by muse, mutect2, varscan2
- VAMP5 | c.111G>A p.L37= | Silent (SNP) | VAF 32/198 reads (16%) | catalogued as COSV100111677; called by muse, mutect2, varscan2
- VIM | c.1297C>T p.L433= | Silent (SNP) | VAF 20/179 reads (11%) | catalogued as rs768266467, COSV56404829, COSV56405361; called by muse, mutect2, varscan2
- WDR53 | c.642T>C p.C214= | Silent (SNP) | VAF 331/656 reads (50%) | catalogued as rs1192767221, COSV100217998; called by muse, mutect2, varscan2
- YEATS2 | c.1110G>A p.K370= | Silent (SNP) | VAF 25/251 reads (10%) | catalogued as COSV100527369; called by muse, mutect2
- YTHDC2 | c.1374G>A p.V458= | Silent (SNP) | VAF 42/116 reads (36%) | catalogued as COSV99362805; called by muse, mutect2, varscan2
- ZNF217 | c.2307T>A p.S769= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV100184110; called by muse, mutect2, varscan2
- ZNF700 | c.1560C>T p.A520= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as rs1300449437, COSV99583189; called by muse, mutect2, varscan2
- AGAP7P | n.1397G>A | RNA (SNP) | VAF 10/40 reads (25%) | called by mutect2, varscan2
- NCAPD2 | c.262+212C>A | Intron (SNP) | VAF 29/205 reads (14%) | catalogued as COSV100216770; called by muse, mutect2, varscan2
- ZNF658B | n.2399G>C | RNA (SNP) | VAF 24/48 reads (50%) | called by mutect2, varscan2
